Gene-level copy-number profile of tumor specimen TCGA-D7-6520-01A from TCGA case TCGA-D7-6520, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 53.3 years (19,467 days).
Specimen TCGA-D7-6520-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.be64b02b-ae3e-43e8-ac51-f4d21c8f2790.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D7-6520-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3e59b4f0-5b6e-4ff7-afed-6c62b2d9321b

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 1: 20; copy number 2: 11,582; copy number 3: 5,808; copy number 4: 33,323; copy number 5: 2,547; copy number 6: 4,794; copy number 7: 1,279; copy number 8: 106; copy number 9: 99; copy number 10: 72; copy number 11: 130; copy number 14: 41.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D7-6520-01A-11D-1799-01): tumor purity 0.52, ploidy 3.86, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,029,594, 2 genes (within-gene range 0–2): MTAP, AL359922.1.
- chr9:21,892,188–22,128,103, 10 genes: AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr9:132,725,578–132,946,874, 4 genes (within-gene range 0–2): AK8, AL445645.1, SPACA9, TSC1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 342 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:83,067,962–83,068,071, 1 gene, copy number 9: RNU6-478P.
- chr10:83,672,406–84,561,263, 21 genes, copy number 9: LINC02650, AC069540.2, AC069540.1, RNU6-129P, AL390786.1, RNU1-65P, HMGN2P8, AL603756.1, GHITM, CERNA2, C10orf99, CDHR1, LRIT2, RGR, LRIT1, LINC00858, CCSER2, RPL12P29, TNPO1P1, CACYBPP1, RPS3AP5.
- chr10:102,673,731–104,455,102, 60 genes, copy number 9 (within-gene range 4–9): ARL3, SFXN2, WBP1L, RNU6-1231P, CYP17A1, PFN1P11, PTGES3P4, AL358790.1, BORCS7, BORCS7-ASMT, U6, AS3MT, RPL22P17, AL356608.3, AL356608.1, CNNM2, AL356608.2, NT5C2, RPS15AP29, MARCKSL1P1, ST13P13, RPEL1, INA, PCGF6, RNU11-3P, TAF5, ATP5MD, MIR1307, PDCD11, CALHM2, AL139339.2, AL139339.1, CALHM1, CALHM3, NEURL1-AS1, NEURL1, AL121929.1, AL121929.3, SH3PXD2A, AL121929.2, Y_RNA, SH3PXD2A-AS1, AL133355.1, STN1, SLK, RN7SL524P, COL17A1, MIR936, SFR1, CFAP43, MIR609, GSTO1, MIR4482, GSTO2, ITPRIP, AL162742.1, AL162742.2, ITPRIP-AS1, CFAP58-DT, CFAP58.
- chr10:109,528,119–109,681,041, 4 genes, copy number 9: PHB2P1, BTF3P15, AL390123.1, XIAPP1.
- chr10:109,940,104–110,304,938, 7 genes, copy number 9 (within-gene range 4–9): ADD3-AS1, ADD3, SNRPGP12, MXI1, AL360182.2, AL360182.1, SMNDC1.
- chr10:112,149,865–115,948,999, 58 genes, copy number 11 (within-gene range 4–11): GPAM, TECTB, MIR6715B, MIR6715A, GUCY2GP, ACSL5, AL157786.1, ZDHHC6, VTI1A, AC022018.1, MIR4295, AL139120.1, AL158212.5, AL158212.3, AL158212.4, AL158212.1, TCF7L2, AL158212.2, RPS15AP30, RNU7-165P, AL133482.1, PPIAP39, HABP2, NRAP, CASP7, AL592546.2, PLEKHS1, MIR4483, AL592546.1, DCLRE1A, NHLRC2, AL592546.3, ADRB1, AC022023.2, RNU6-709P, UBE2V1P5, CCDC186, AC022023.1, MIR2110, TDRD1, VWA2, AURKAP2, AC005383.1, AFAP1L2, RN7SL384P, AL133384.2, ABLIM1, AL133384.1, PPIAP19, AL137025.1, TAF9BP2, FAM160B1, RPL15P13, TRUB1, RNU6-1121P, LINC02626, ATRNL1, AC016042.1.
- chr10:116,427,847–126,388,455, 185 genes, copy number 10–14 (within-gene range 4–14) (broad region; genes not listed).
- chr11:32,892,811–33,105,943, 6 genes, copy number 9 (within-gene range 6–9): QSER1, Y_RNA, DEPDC7, TCP11L1, PIGCP1, LINC00294.

Autosomal genes at a single copy (total copy number 1): 7. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
